Somatic mutation profile of tumor specimen TARGET-20-PASCRZ-03A (aliquot TARGET-20-PASCRZ-03A-02D) from TARGET case TARGET-20-PASCRZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.7 years (5,356 days).
Specimen TARGET-20-PASCRZ-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf1017ef-4013-41e6-9599-b60f4eee68ce.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASCRZ-14A (Bone Marrow Normal), aliquot TARGET-20-PASCRZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83b4bb24-765e-41a7-a195-a09dbf4f43db

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 32/130 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- FLT4 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV56105468; called by muse, mutect2, varscan2
- PRUNE2 | c.*2684T>C | 3'UTR (SNP) | VAF 94/191 reads (49%) | catalogued as rs1483781199; called by muse, mutect2, varscan2
